Surgical pathology report (de-identified scan), TCGA case TCGA-WK-A8XT, project TCGA-SARC (Sarcoma), tissue source site Brigham and Women's Hospital, specimen TCGA-WK-A8XT-01A (Primary Tumor).

[page 1 of 3]
Sex:F

Pathology Report

Accession Number:
Type: Surgical Pathology
Specimen Type: Kidnev. partial ~~or~~ total resection
Procedure Date:
Ordering Provider:

Report Status: Amend/Addenda

CASE:

PATIENT: ~~REDACTED~~

***** Addended Report *****

Resident:

Pathologist:

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "LEFT KIDNEY, NEPHRECTOMY":

POORLY DIFFERENTIATED MONOPHASIC SYNOVIAL SARCOMA (3.2 cm) involving kidney.
Mitoses number up to 50 per 10 HPF.
No necrosis identified.
Focal lymphovascular invasion is present.
Ureter, artery, vein, and soft tissue margins are negative for tumor.
Tumor is 0.7 cm from the closest soft tissue margin.

NOTE: The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

CLINICAL DATA:

History: History of desmoid tumors. Now with synovial sarcoma L kidney.
Operation: Resection L retroperitoneal mass, left nephrectomy.
Operative Findings: Not provided.
Clinical Diagnosis: Left retroperitoneal sarcoma.

TISSUE SUBMITTED:

A/1) left kidney (tissue bank).

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "left kidney", and consists of a 189-gram left nephrectomy specimen including kidney (12.2 x 6.2 x 4.4 cm) with minimal surrounding attached perirenal fat measuring up to 2.0 cm in thickness. Extending from the renal pelvis, is a ureter (7.0 cm in length x 0.4 cm in diameter), renal vein (1.2 cm in length x 0.7 cm in diameter) and renal artery (1.6 cm in length x 0.6 cm in diameter). There is no adrenal gland grossly identified. The perirenal fat and capsule are inked black. In the mid to lower pole of the kidney, there is a tan/pink focally hemorrhagic soft friable slightly mucinous interpolar mass (3.2 x 2.7 x 2.8 cm) that is located 2.1 cm to the artery, 3.0 cm to the vein and 5.8 cm to the ureter. No vascular invasion is identified. The mass is located in the cortex and abuts the renal pelvis and is located 0.2 cm to the inked fatty margin. The mass abuts an area of hemorrhage and the lower pole (2.5 x 1.0 x 0.5 cm). There are two smooth lined cystic areas immediately adjacent to the mass, measuring up to 0.5 cm in greatest dimension. The remainder of the renal cortex is tan/red with a mildly effaced corticomedullary junction. The papillae are mildly blunted and the average cortical thickness is 1.0 cm. No calculi are seen. The adipose tissue in the hilar region is thinly sectioned and palpated and no lymph nodes are identified. Focal portions of the perirenal fat of the cortical surface retracted during the fixing process. Representative sections of the tumor are submitted for cytogenetics, electron microscopy, quick fix, and tissue bank. Representative sections of normal kidney are submitted for tissue bank, electron microscopy, and immunofluorescence. Also received with the specimen is a portion of tan/yellow lobulated fatty tissue, which is unoriented, measures 3.2 x 2.2 x 1.3 cm, and is representatively submitted for histological examination. Gross photographs of the specimen are taken.

Micro A1: Tumor quick fix, 2 frags,

ICD-O-3
Sarcoma, synovial monophasic
fibrous 9041/3
Site @ Kidney NOS C64.9
JW 5/5/15

[page 2 of 3]
Pathology Report

Micro A2: Renal vein artery and ureter margins, en face, 3 frags, 1
Micro A3: Tumor to capsule/perirenal fat margin, 1 frag,
Micro A4: Tumor to capsule/perirenal fat and adjacent parenchyma, 1 frag, 1
Micro A5: Tumor to adjacent parenchyma, 1 frag, 1
Micro A6: Tumor to adjacent parenchyma including area of hemorrhage, 1 frag,

Micro A7: Tumor in relation to cyst, 1 frag,
Micro A8: Tumor and area of hemorrhage, 1 frag, 1
Micro A9: Normal kidney, 2 frags,
Micro A10: Fragment of lobulated fatty tissue, 1 frag,

CASE NUMBER:

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Final Diagnosis by _____, Electronically signed on _____

ADDENDUM:

RENAL PATHOLOGY EVALUATION OF THE KIDNEY PARENCHYMA:

LEFT KIDNEY (RADICAL NEPHRECTOMY):

IgA NEPHROPATHY, MILD (SEE NOTE)

MODERATE CHRONIC CHANGES OF THE KIDNEY, INCLUDING:

- FOCAL GLOBAL GLOMERULOSCLEROSIS (14% OF GLOMERULI)
- FOCAL TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS (10% OF THE PARENCHYMA)
- ARTERIAL AND ARTERIOLAR SCLEROSIS, MODERATELY SEVERE (SEE NOTE)

NOTE:

This nephrectomy specimen shows moderate chronic changes of the parenchyma, as detailed above. The biopsy also reveals sparse granular deposits of IgA/IgM in the mesangium, most suggestive of a mild form of IgA nephropathy; there are no signs of a currently active glomerulitis. The chronic changes may be related to a moderate degree of vascular sclerosis; a potential contribution of the IgA nephropathy to the chronic changes is probably minimal.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A9) were evaluated using H&E, PAS, Jones' silver methenamine, and AFOG (trichrome) stains by light microscopy. An H&E-stained frozen section and semi-thin toluidine blue-stained section were also evaluated by light microscopy.

The sample consists of cortex and medulla. There are two hundred nine (209) glomeruli present, of which thirty (30) (14%) show signs of hypoperfusion or global or segmental glomerulosclerosis. The remaining glomeruli reveal a small tuft, open capillaries, and frequent wrinkling of the basement membranes. The mesangium is mildly expanded but does not have significant hypercellularity. Signs of active inflammation, fibrinoid necrosis of the tuft, or crescent formation are not evident. On PAS and Jones' silver stain, the glomerular basement membranes appear irregular in thickness but without discernible "spikes"; few loops reveal distinctive double contours. Tubules reveal mild patchy atrophy and few contain PAS-positive casts. The interstitium is focally expanded by connective tissue and mild focal mononuclear inflammation with two

[page 3 of 3]
Sex: F

Pathology Report

discrete perivascular lymphoid aggregates with germinal centers. Approximately 10% of the sample shows tubular atrophy and interstitial fibrosis, as evidenced on the trichrome stains (AFOG). Arteries show moderate changes in the wall, with duplication of the cells and matrix layers of the media and subintimal accumulation of connective tissue; these changes have resulted in irregular narrowing of the lumina. Arterioles reveal sclerosis of the media, and focal hyperplasia of the cells in this layer. There are interstitial calcium phosphate crystals in the renal papilla.

IMMUNOFLUORESCENCE MICROSCOPY REPORT KIDNEY BIOPSY

The sections were incubated with antibodies specific for the heavy chains of IgG, IgA, and IgM, for kappa light chains, lambda light chains, C3, C1q, albumin, and fibrin-related antigens.

The sample consists of kidney cortex and outer medulla. There are twenty-two (22) glomeruli present. One (1) glomerulus is globally sclerosed. There is diffuse granular deposition of C3 (trace), IgM (1+/4+), and IgA (1+/4+, lambda stronger than kappa) along the peripheral capillary walls and in the mesangial areas; C1q is negative. Fibrin deposits (1+/4+) are present segmentally within the glomerular tufts and in Bowman's space in one (1) glomerulus. Isolated glomerular epithelial cells in three (3) glomeruli contain protein reabsorption granules (albumin, IgG, IgA, C3). Several casts in the distal tubules are reactive for polyclonal IgA. The interstitium reveals scattered fibrin deposits. Coarse IgM and C3 deposits (1+/4+) are present in the walls of several arterioles. Arterioles show focal C3 reactivity. There is no difference noted in the intensity of the staining for kappa and lambda light chains in the casts or in the background of the tissue.

ELECTRON MICROSCOPY REPORT KIDNEY BIOPSY

Blocks: 4; blocks examined: 4 thick sections; 1 thin section.

The tissue examined at the ultrastructural level includes two (2) glomeruli. Few capillary loops appear collapsed with wrinkling of the basement membrane (hypoperfusion). There is only minimal focal effacement of visceral epithelial cell foot processes. The basement membranes appear of normal thickness. There are no electron dense deposits present along the peripheral capillary loops. The mesangium is expanded by matrix and increased cell projections. There are few small and often ill-defined electron dense deposits present in the mesangial areas. Several arteries were also examined. They reveal mild distortion of the vessel wall, with fine-granular material between the cellular and matrix components of the media.

Addendum #1 by

, Electronically signed on

Source: NCI Genomic Data Commons file 2c88b756-83fb-430e-9ce7-7393e7e2fd95 (TCGA-WK-A8XT.0AEE101C-6276-4636-AEAC-FB1C62062642.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).